CPTAC case C3L-02968 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/32647966-e243-4cbf-ad05-6041071853c4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 64.8 years (23,682 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,795 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,795 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6 cm (a second GDC size field records 2.8 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 19; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 326 days; Disease response: Tumor Free.
- Days to follow up: 692 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,029 days (2.8 years); Disease response: Complete Response.
- Days to follow up: 1,029 days (2.8 years); Disease response: Tumor Free.
- Days to follow up: 1,375 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,795 days (4.9 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 72.12 kg; Height: 167.64 cm; BMI: 25.66; DLCO (% of predicted): 50; FEV1/FVC after bronchodilator (%): 64; FEV1/FVC before bronchodilator (%): 57; FEV1 after bronchodilator (% of reference): 45; FEV1 before bronchodilator (% of reference): 26.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Cigarettes per day: 20; Tobacco smoking quit year: 2012; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02968-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 299 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02968-22: Section location: Left Upper Lobe; Percent tumor nuclei: 85; Percent necrosis: 10.
- Sample C3L-02968-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 1,082 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02968-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
